CCDI case PBCGVV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/40e4ff99-93c3-4c2e-be5a-896157135de2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.4 years (5,253 days).

Biospecimens (1 sample)
- Sample 0DRY7X: Tissue type: Tumor; Specimen type: Solid Tissue.
